Surgical pathology report (de-identified scan), TCGA case TCGA-24-1556, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site Washington University, specimen TCGA-24-1556-01A (Primary Tumor).

[page 1 of 6]
Physician(s):

Other Related Clinical Data:

DIAGNOSIS: SPECIMEN LABELED "LEFT OVARIAN TUMOR," EXCISION

- POORLY DIFFERENTIATED PAPILLARY SEROUS ADENOCARCINOMA INVOLVING SURFACE, 15.0 CM

OVARY, LEFT, SALPINGO-OOPHORECTOMY

- PAPILLARY SEROUS ADENOCARCINOMA

UTERUS, CERVIX, TOTAL ABDOMINAL HYSTERECTOMY

- HYPERKERATOSIS \T\ PARAKERATOSIS

UTERUS, ENDOMETRIUM, TOTAL ABDOMINAL HYSTERECTOMY

- AUTOLYZED ENDOMETRIUM

UTERUS, MYOMETRIUM, TOTAL ABDOMINAL HYSTERECTOMY

- NO HISTOPATHOLOGIC ABNORMALITY

UTERUS, SEROSA, TOTAL ABDOMINAL HYSTERECTOMY

- EXTENSIVE ADHESIONS

OVARY, RIGHT, SALPINGO-OOPHORECTOMY

- FOCAL PARA-OVARIAN ADHESIONS

- CORPUS LUTEUM

FALLOPIAN TUBE, RIGHT, SALPINGO-OOPHORECTOMY

- EXTENSIVE PERITUBAL ADHESIONS WITH ASSOCIATED MESOTHELIAL HYPERPLASIA

RECTOSIGMOID NODULE, EXCISION

- METASTATIC PAPILLARY SEROUS ADENOCARCINOMA

[page 2 of 6]
[REDACTED]

OMENTUM, OMENTECTOMY

- MATURE ADIPOSE TISSUE WITH FOCAL MESOTHELIAL HYPERPLASIA
- NO CARCINOMA IDENTIFIED

LYMPH NODES, RIGHT PELVIC, EXCISION

- NO CARCINOMA IDENTIFIED IN EIGHT LYMPH NODES (0/8)

LYMPH NODE, RIGHT PERI-AORTIC, EXCISION

- NO CARCINOMA IDENTIFIED IN ONE LYMPH NODE (0/1)

LYMPH NODES, LEFT PELVIC, EXCISION

- NO CARCINOMA IDENTIFIED IN SIX LYMPH NODES (0/6)

LYMPH NODES, LEFT PERI-AORTIC, EXCISION

- NO CARCINOMA IDENTIFIED IN THREE LYMPH NODES (0/3)

[REDACTED] By this signature, I attest that the above diagnosis is based upon my personal examination of the slides (and/or other material indicated in the diagnosis).

[REDACTED]

Intraoperative Consultation: An intraoperative consultation was obtained and interpreted as: [REDACTED] An 830 gram specimen with a mostly smooth surface with some papillary projections and measuring 15 x 14 x 9 cm. Sectioning reveals the cut surface is solid, soft, and pink-tan. Representative portions are submitted for frozen section," by [REDACTED]

[REDACTED] Ovary, left, excision

- "Carcinoma consistent with Mullerian origin," [REDACTED]

[REDACTED] Microscopic Description and Comment: Microscopic examination substantiates the above cited diagnosis. [REDACTED]

History: The patient is a [REDACTED] with a pelvic mass, pleural effusion, and elevated CA125. Operative procedure: Examination under anesthesia, exploratory laparotomy, total abdominal hysterectomy with bilateral salpingo-oophorectomy, pelvic lymph node dissection, radical tumor debulking, and omentectomy.

Specimen(s) Received:

- A: LEFT OVARIAN TUMOR
- B: LEFT OVARY AND TUBE
- C: UTERUS, CERVIX, AND RIGHT SIDE OVARY
- D: RECTOSIGMOID MESENTARY NODULE
- E: RIGHT PELVIC LYMPH NODE
- F: RIGHT PERI-AORTIC LYMPH NODE
- G: LEFT PELVIC LYMPH NODE
- H: LEFT PERI AORTIC LYMPH NODE
- I: OMENTUM, ROUTINE

Gross Description The first specimen is received fresh from the operating room, labeled with the patient's name and "#1, left ovarian tumor" and consists of a 15 x 14 x 9 cm, 837 gram mass with a mostly smooth and shiny purple-pink surface with focal tan papillary projections. It has a spongy, semi-solid, partially cystic cut surface with some areas of

[page 3 of 6]
[REDACTED]

grey-to-yellow tissue, possibly representing necrosis. At one portion of the mass, it is torn and possibly ruptured over a surface of [REDACTED]. At this site, slightly papillary and nodular brown tumor grossly projects. Labeled A1 - ES1; A2 through A7 - representative tumor sections with surface tumor in A6 and A7. [REDACTED]

The remaining specimens are all received in containers of formalin, each labeled with the patient's name. The second is additionally labeled "#2, left ovary and tube." It consists of an 11 x 9.5 x 5 cm, lobulated white-tan tumor mass. The external surface is smooth and lobulated over the majority, but with several sites of papillary tan tissue apparently rupturing through the capsule and also involving the capsular surface. It is bisected to reveal a fleshy pink-tan, solid tumor mass with central areas of white and yellow fibrous tissue. A small portion of remaining ovary measuring 3.0 x 1.5 x 0.8 cm which has a variegated cut surface with brown, yellow, and white scalloped nodules. The ovary is adhered to and possibly continuous with the large mass. On numerous sections through the apparent ovarian hilum and soft tissue in this region, no definitive fallopian tube is identified. Labeled B1 and B2 - tumor with areas of rupture or serosal implantation; B3 through B5 - fleshy tumor mass; B6 - uninvolved ovary; B7 - ovarian hilum and potential fallopian tube. [REDACTED]

The third specimen is additionally labeled "#3, uterus, cervix, right salpingo-oophorectomy" and consists of a 163 gram, 10 x 7 x 6.5 cm uterus with attached cervix and right ovary and fallopian tube. The 4.5 x 4.5 cm ectocervix has smooth tan-pink epithelium, an unremarkable underlying transformation zone, and an endocervical canal with finely folded white-tan epithelium and no focal lesions. The endometrial cavity measures 7.5 cm from fundus to endocervix x 3.5 cm from cornu to cornu, and has a 0.2 cm in average thickness tan endometrium without polyps or mass lesions. The fibrous brown-tan myometrium has a maximal thickness of 1.8 cm without focal lesions, while its overlying serosa has numerous dark brown-to-tan adhesions with focal, somewhat gelatinous tissue concerning for implants. The right fallopian tube measures 5.5 cm in length by a diameter of up to 1 cm. It has a slightly red-brown-tan serosal surface with delicate purple fimbria. No gross tumor implants are identified and cross sections are unremarkable. The 3.5 x 2.5 x 1 cm right ovary has a lobulated white external surface, and on cut sections, has a 0.8 cm smooth-walled cyst and a larger 1.8 cm cyst with clear fluid and a finely folded brown-tan wall averaging 0.2 cm in thickness. No papillary projections or discrete tumor nodules are present. Labeled C1 and C2 - anterior cervix and endomyometrium; C3 and C4 - posterior cervix and endomyometrium; C5 - uterine serosa; C6 - right fallopian tube; C7 - right ovary. [REDACTED]

The fourth specimen is additionally labeled "#4, rectosigmoid mesentery nodule" and consists of 4.0 x 4.0 x 1.4 cm of nodular, rubbery tan-brown tumor and attached blood clot. Labeled D1 and D2. [REDACTED]

The fifth specimen is additionally labeled "#5, right pelvic lymph node" and consists of 5.5 x 4.4 x 1.5 cm of fibrofatty yellow and brown tissue which is dissected to show several lymph node candidates measuring from 0.5 up to 2.5 cm in maximal dimension. A 1.0 cm lymph node has slightly spongy and papillary brown-tan material within it. Labeled E1 and E2 (all single). [REDACTED]

The sixth specimen is additionally labeled "#6, right periaortic lymph nodes" and consists of a 2.9 x 1.5 x 0.8 cm fibrofatty yellow-brown tissue fragment which is dissected to show a single brown-tan lymph node measuring 2 cm in maximal dimension. Bisected. [REDACTED]

The seventh specimen is additionally labeled "#7, left pelvic lymph nodes" and consists of two large fibrofatty brown-yellow tissue fragments measuring 6 x 6 x 1.8 cm in aggregate.

[page 4 of 6]
[REDACTED]

They are dissected to reveal several lymph node candidates, some of which are fat replaced, measuring from 0.5 up to 2.5 cm in maximal dimension. [REDACTED]

The eighth specimen is additionally labeled "#8, left periaortic" and consists of 4.0 x 2.5 x 1 cm fragment of fibrofatty brown and yellow tissue which is dissected to show lymph node candidates measuring from 0.7 up to 1.4 cm in maximal dimension. One lymph node has slightly spongy and papillary-appearing brown-tan tissue. [REDACTED]

The final specimen is additionally labeled "#9, omentum" and consists of several fragments of fibrofatty brown and yellow omentum measuring 12.5 x 10.5 x 2 cm in total. On palpation and serial sectioning, the tissue is fibrofatty and friable without discrete lesions identified. [REDACTED]

[REDACTED] [REDACTED]

Synopsis SYNOPSIS REPORTING FORM FOR MALIGNANT OVARIAN NEOPLASMS 1. PRESENT

A neoplasm is

2. The HISTOLOGIC DIAGNOSIS is: Serous adenocarcinoma
3. The LOCATION(S) OF THE PRIMARY TUMOR(S) is/are: Left ovary only
5. The NUCLEAR (BRODERS') GRADE of the tumor is: G3 (Poorly-differentiated)
6. Tumor IS identified on the ovarian surface(s).
- 7 Tumor DOES invade the mesovarium.
8. Invasion of adjacent fallopian tube CANNOT BE EVALUATED.
9. Tumor DOES invade the pelvic soft tissue.
10. Tumor involvement of the pelvic peritoneum is PRESENT.
11. Metastatic involvement of the EXTRAPELVIC peritoneum is ABSENT.
12. Metastatic involvement of the omentum is ABSENT.
13. The maximum dimension of tumor implants outside the true pelvis is: 0 cm.
14. Metastatic involvement of the uterine serosa is ABSENT.
15. Metastatic involvement of the endometrium is ABSENT.
16. Regional lymph node metastases are ABSENT.
17. The total number of regional lymph nodes examined is: 18.
18. The total number of metastatically-involved regional lymph nodes is: 0 Extranodal extension by tumor is NOT APPLICABLE; no nodal metastases are present
19. DETAILED STAGING INFORMATION:

Based on the above information, the PRIMARY TUMOR is classified as:

TNM Scheme	FIGO Scheme	Definition
------------	-------------	------------

[page 5 of 6]
T2b
tumor to pelvic soft tissue

IIB

Extension of

THE REGIONAL LYMPH NODES are classified as: N0 (Nodes are free of metastases)

THE STATUS OF DISTANT TUMOR SITES is classified as: MX (Status cannot be assessed)

20. The FINAL AJCC/UICC/FIGO STAGE IS: AJCC/UICC/FIGO

X Insufficient data to assign stage

The pathologic stage assigned here should be regarded as provisional, and may change after integration of clinical data not provided with this specimen.

Source: NCI Genomic Data Commons file 21233761-0f1f-4da7-9729-f0dda47f49b1 (TCGA-24-1556.75C91323-45A7-4629-B014-F7EDA2F1075E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).